TCGA case TCGA-C5-A1BM — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7fb8e7be-4118-41f8-b785-5cbb0afdb8b7

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Dead; Days to death: 2,520 days (6.9 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 78.9 years (28,815 days); Year of diagnosis: 1997; Method of diagnosis: Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Uterus.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Lymph node involved site: Intra-Abdominal, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 8; Lymph nodes tested: 23; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 154 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Day 102 (preoperative): Days to imaging: 102 days; Imaging type: PET; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Days to follow up: 2,520 days (6.9 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 171 cm; BMI: 19.2.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-C5-A1BM-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-C5-A1BM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1BM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 2; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 3; Tobacco smoking history indicator: 4; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Other pos node location: perigastric; Margins involved hysterectomy: Positive vaginal margin; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Present; Corpus involvement: Present; Days to ct scan ab pelvis: 22.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator); Pos lymph node location: Other Location, specify.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Extra-Pelvic Metastatic Disease Present.
- Follow-up form: Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Days to brachytherapy begin occurrence: 171; Days to brachytherapy end occurrence: 186; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; New tumor event diagnosis indicator: No.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,520 days; disease-specific survival: no event (censored), 2,520 days; disease-free interval: no event (censored), 2,520 days; progression-free interval: no event (censored), 2,520 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1BM-01A-11D-A13V-01): tumor purity 0.67, ploidy 2.04, whole-genome doublings 0.
